Somatic mutation profile of tumor specimen MMRF_1286_1_BM_CD138pos (aliquot MMRF_1286_1_BM_CD138pos_T1_KBS5U_L02855) from MMRF case MMRF_1286, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.3 years (27,125 days).
Specimen MMRF_1286_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 246192f3-49a5-4409-8b73-cc2f1f56daff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1286_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1286_1_PB_Whole_C3_KBS5U_L02867; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59a55326-a2b6-452f-83fa-96ab9c241b40

The open-access MAF lists 125 somatic variants for this specimen: 36 protein-altering or splice-affecting, 17 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 40, Missense Mutation 29, Intron 18, Silent 17, 5'UTR 7, 3'Flank 5, Splice Site 2, Nonsense Mutation 2, 5'Flank 1, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.3790C>T p.R1264W | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438520326, COSV53132834; called by muse, mutect2, varscan2
- CCDC171 | c.3244C>T p.Q1082* | Nonsense Mutation (SNP) | VAF 48/116 reads (41%) | catalogued as rs1337997188, COSV99899605; called by muse, mutect2
- COL21A1 | c.2066G>A p.G689D | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1348329661; called by muse, varscan2
- GRIA1 | c.1122C>G p.D374E | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53592013; called by muse, mutect2, varscan2
- GRIK4 | c.2491C>T p.L831F | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.475); catalogued as COSV70806920; called by muse, mutect2, varscan2
- HAUS2 | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773437782, COSV53000045; called by muse, mutect2
- IGLV3-1 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 54/56 reads (96%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs372924773; called by muse, varscan2
- IGLV3-1 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as rs367971405; called by muse, mutect2, varscan2
- MAGEC1 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53573965, COSV53580475; called by muse, mutect2, varscan2
- NDN | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100086520; called by muse, mutect2, varscan2
- TIAM2 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1275205076; called by muse, mutect2, varscan2
- TPSB2 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs760268825, COSV52354431, COSV52357205; called by muse, mutect2, varscan2
- XKR7 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1264709223, COSV73813385, COSV73813447; called by muse, mutect2, varscan2
- ABHD17B | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ALB | c.483-2A>G p.X161_splice | Splice Site (SNP) | VAF 93/180 reads (52%) | called by muse, mutect2, varscan2
- CCDC102B | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CEP76 | c.1262C>G p.T421S | Missense Mutation (SNP) | VAF 96/209 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CPA2 | c.487-1G>T p.X163_splice | Splice Site (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- DDI1 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ERICH3 | c.2117A>T p.E706V | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- GALNT18 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- GRHL1 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV4-1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV5-2 | c.17A>C p.H6P | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, varscan2
- KAT6B | c.2824C>A p.L942M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MASP2 | c.1525T>C p.Y509H | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- OR2Z1 | c.944G>C p.*315Sext*7 | Nonstop Mutation (SNP) | VAF 228/299 reads (76%) | called by muse, mutect2, varscan2
- PHF20L1 | c.-35A>C | Splice Region (SNP) | VAF 148/298 reads (50%) | called by muse, mutect2, varscan2
- PLCD3 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PSMA1 | c.611A>G p.D204G | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SRRM2 | c.2619del p.F873Lfs*9 | Frame Shift Del (DEL) | VAF 89/173 reads (51%) | called by mutect2, varscan2
- TENM1 | c.4071G>C p.M1357I | Missense Mutation (SNP) | VAF 72/72 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TNFSF10 | c.667A>G p.M223V | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- UBE2E3 | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- WLS | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); called by muse, mutect2
- ZNF816 | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY5 | c.2604G>A p.E868= | Silent (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- DCLK1 | c.277C>A p.R93= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- DNTTIP2 | c.135T>C p.T45= | Silent (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- EPHB6 | c.42G>A p.A14= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs762187458; called by muse, mutect2, varscan2
- FLNC | c.549T>G p.R183= | Silent (SNP) | VAF 50/102 reads (49%) | called by muse, mutect2, varscan2
- HMBOX1 | c.102G>A p.R34= | Silent (SNP) | VAF 140/282 reads (50%) | called by muse, mutect2, varscan2
- KRT78 | c.1308G>A p.S436= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs1342427291; called by muse, mutect2, varscan2
- MAST4 | c.4626C>T p.D1542= (on ENST00000403625 / NM_001164664.2; = p.D1353= on NM_015183.3) | Silent (SNP) | VAF 46/164 reads (28%) | catalogued as rs761796064, COSV55132662; called by muse, mutect2, varscan2
- OBSCN | c.13530C>T p.D4510= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs1469709345; called by muse, mutect2, varscan2
- OR2Z1 | c.318G>C p.L106= | Silent (SNP) | VAF 264/376 reads (70%) | called by muse, mutect2, varscan2
- PCDHA1 | c.2034G>A p.A678= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs562110007, COSV65375424; called by muse, mutect2, varscan2
- SHFL | c.36C>G p.V12= | Silent (SNP) | VAF 179/573 reads (31%) | called by muse, mutect2, varscan2
- TPSB2 | c.157C>A p.R53= | Silent (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- TSSK2 | c.957C>T p.T319= | Silent (SNP) | VAF 134/268 reads (50%) | called by muse, mutect2, varscan2
- TUT1 | c.1536G>A p.L512= | Silent (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- ZNF33B | c.1734G>A p.E578= | Silent (SNP) | VAF 84/155 reads (54%) | called by muse, mutect2, varscan2
- ZNF675 | c.687A>G p.K229= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs745636351; called by muse, mutect2, varscan2
- AATK | c.189+1538C>A | Intron (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2
- ACOT11 | c.*121C>T | 3'UTR (SNP) | VAF 43/79 reads (54%) | catalogued as rs931164612; called by muse, mutect2, varscan2
- ADGRB2 | c.*38T>G | 3'UTR (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- AL049777.1 | n.510+4504G>C | Intron (SNP) | VAF 12/24 reads (50%) | catalogued as rs957433756; called by muse, varscan2
- BTG1 | c.-195T>G | 5'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81947934 ins A | 3'Flank (INS) | VAF 43/111 reads (39%) | called by mutect2, pindel, varscan2
- CCDC102B | c.1263+102C>T | Intron (SNP) | VAF 76/261 reads (29%) | called by muse, mutect2, varscan2
- CCDC50 | c.*2842A>G | 3'UTR (SNP) | VAF 48/87 reads (55%) | called by muse, mutect2, varscan2
- CCT6P3 | chr7:65078632 C>T | 3'Flank (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- CDK11B | c.495-867C>T | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- CEP44 | c.*697G>A | 3'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as rs1417932355; called by muse, mutect2, varscan2
- CEP57 | c.807+230T>C | Intron (SNP) | VAF 54/95 reads (57%) | called by muse, mutect2, varscan2
- CFAP20DC | c.*291_*292delinsC | 3'UTR (DEL) | VAF 43/140 reads (31%) | called by pindel, varscan2*
- DEPDC1B | c.48+25G>A | Intron (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- DHCR24 | c.231+118dup | Intron (INS) | VAF 21/48 reads (44%) | catalogued as rs767052495; called by mutect2, varscan2
- ECE1 | c.4-8513A>G | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2
- EGFLAM | c.713-2339A>C | Intron (SNP) | VAF 147/296 reads (50%) | called by muse, mutect2, varscan2
- ELF3 | c.*587G>T | 3'UTR (SNP) | VAF 43/70 reads (61%) | called by muse, mutect2, varscan2
- ERO1A | c.*2352G>A | 3'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- FAM110D | c.*450A>C | 3'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- FAM71C | c.*196C>G | 3'UTR (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- GPR55 | chr2:230907326 C>T | 3'Flank (SNP) | VAF 6/29 reads (21%) | catalogued as rs1049956949; called by muse, mutect2
- GRIN3A | c.-351C>G | 5'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- H2BC7 | c.*122C>A | 3'UTR (SNP) | VAF 72/140 reads (51%) | catalogued as rs904321531; called by muse, mutect2, varscan2
- HCN1 | c.*1343G>T | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- HELZ | c.-9C>T | 5'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- HERC2P3 | n.2328G>A | RNA (SNP) | VAF 38/151 reads (25%) | catalogued as rs187377229; called by muse, mutect2, varscan2
- HMCN1 | c.*703G>T | 3'UTR (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- JMJD1C | c.*338G>A | 3'UTR (SNP) | VAF 27/67 reads (40%) | catalogued as rs893281975; called by muse, mutect2, varscan2
- KITLG | c.*160A>G | 3'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- KITLG | c.15+71G>C | Intron (SNP) | VAF 25/67 reads (37%) | called by muse, varscan2
- KLC1 | c.*7623G>A | 3'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, varscan2
- LRP12 | c.*252T>C | 3'UTR (SNP) | VAF 47/101 reads (47%) | called by muse, mutect2, varscan2
- LRRN3 | c.-341T>G | 5'UTR (SNP) | VAF 31/49 reads (63%) | called by muse, mutect2, varscan2
- ME3 | c.1380+102A>T | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- NCKAP5L | c.3793-119G>T | Intron (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- NFX1 | c.2424+1030G>A | Intron (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- NPAS3 | chr14:33803075 T>A | 3'Flank (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- NT5DC1 | c.*105C>A | 3'UTR (SNP) | VAF 54/110 reads (49%) | called by muse, mutect2, varscan2
- OR8S1 | chr12:48528252 G>A | 3'Flank (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67448G>C | Intron (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- PCSK5 | c.1900+222C>A | Intron (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- PDS5B | c.*1145A>T | 3'UTR (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- PIAS1 | c.*2817_*2820del | 3'UTR (DEL) | VAF 3/30 reads (10%) | catalogued as rs1482905395; called by mutect2, pindel
- PON1 | c.*1127T>G | 3'UTR (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- PRKCA | c.-92C>T | 5'UTR (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- PRR14L | c.-18T>C | 5'UTR (SNP) | VAF 96/192 reads (50%) | called by muse, varscan2
- RBM18 | c.*2337G>C | 3'UTR (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- RBM46 | c.1403-393A>T | Intron (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- REEP3 | c.*2130C>T | 3'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- RHOU | c.*2274G>C | 3'UTR (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- RTKN2 | c.*1684C>T | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- SHISA9 | c.*155C>T | 3'UTR (SNP) | VAF 99/184 reads (54%) | catalogued as rs759203048; called by muse, mutect2, varscan2
- SHPK | c.*1102G>A | 3'UTR (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.-464G>A | 5'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- STK32A | c.*3830T>C | 3'UTR (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- TECRL | chr4:64409464 A>G | 5'Flank (SNP) | VAF 72/147 reads (49%) | called by muse, mutect2, varscan2
- TMEM170A | c.*3365C>G | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- TMPPE | c.*689C>T | 3'UTR (SNP) | VAF 56/104 reads (54%) | catalogued as rs917502206, COSV56561910; called by muse, mutect2, varscan2
- TNFRSF19 | c.*2575G>T | 3'UTR (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- TTN | c.51128-30C>G | Intron (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- UBR3 | c.*1582C>A | 3'UTR (SNP) | VAF 43/98 reads (44%) | catalogued as COSV55855796; called by muse, mutect2, varscan2
- UQCC3 | c.*737C>G | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- VAMP2 | c.*1620T>C | 3'UTR (SNP) | VAF 6/33 reads (18%) | catalogued as rs1314353122; called by muse, varscan2
- WDR38 | c.*2A>C | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- ZFR2 | c.53+16340_53+16366del | Intron (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel
- ZNF197 | c.*3603G>A | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- ZNF28 | c.*1397A>T | 3'UTR (SNP) | VAF 44/79 reads (56%) | called by muse, mutect2, varscan2
- ZNF337 | c.*76G>A | 3'UTR (SNP) | VAF 3/42 reads (7%) | catalogued as rs1194369207; called by muse, mutect2
- ZNF704 | c.*765C>T | 3'UTR (SNP) | VAF 37/82 reads (45%) | catalogued as rs1399944758; called by muse, varscan2
- ZNF709 | c.*2764C>T | 3'UTR (SNP) | VAF 32/64 reads (50%) | called by muse, varscan2
- ZNF709 | c.*2489C>G | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
